Somatic mutation profile of tumor specimen 0DWBCE from CCDI case PBCNWG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 2.9 years (1,075 days).
Specimen 0DWBCE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e2f9327-d939-4f07-b050-c81ca3ce5052.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWBCQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c67a28b5-3d1b-4dde-8091-093a00a4b488

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERMAP | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 349/818 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as rs772808307, COSV60274321; called by muse, mutect2, varscan2
- KCNH3 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 115/267 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1179986411; called by muse, mutect2, varscan2
- MAD1L1 | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 162/339 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1384390736, COSV56235186; called by muse, mutect2, varscan2
- TAF1 | c.4389G>A p.E1463= (on ENST00000373790 / NM_138923.4; = p.E1484= on NM_004606.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 184/525 reads (35%) | catalogued as COSV52118791; called by muse, mutect2, varscan2
- APPL2 | c.13G>C p.D5H | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- C10orf71 | c.3548G>A p.R1183Q | Missense Mutation (SNP) | VAF 78/589 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GIT2 | c.1037T>C p.V346A (on ENST00000355312 / NM_057169.5; = p.V348A on NM_014776.5) | Missense Mutation (SNP) | VAF 120/871 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- PTCHD1 | c.1747G>C p.V583L | Missense Mutation (SNP) | VAF 50/784 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.011); called by muse, mutect2
- SERPINB1 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 71/470 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- APOB | c.7182T>C p.V2394= | Silent (SNP) | VAF 113/698 reads (16%) | called by muse, mutect2, varscan2
- CCDC185 | c.918G>T p.L306= | Silent (SNP) | VAF 594/959 reads (62%) | called by muse, mutect2, varscan2
- MSLN | c.687C>T p.G229= | Silent (SNP) | VAF 61/133 reads (46%) | catalogued as rs762714076; called by muse, mutect2, varscan2
- USP51 | c.906A>G p.K302= | Silent (SNP) | VAF 234/262 reads (89%) | called by muse, mutect2, varscan2
- FGD1 | c.-56C>T | 5'UTR (SNP) | VAF 22/49 reads (45%) | catalogued as rs1431796098; called by muse, mutect2, varscan2
